TARGET case TARGET-15-SJMPAL019076 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1e10278b-1367-4a3f-b2ad-89566bbc3e5c

Demographics
Sex at birth: male; Age at index: 5 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 5.5 years (2,017 days); Year of diagnosis: 1995; Days to last follow up: 5,297 days (14.5 years).

Follow-up (1 entry)
- Days to follow up: 5,297 days (14.5 years); First event: Relapse; Year of follow up: 2009.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 2.8 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL019076-04A.1, TARGET-15-SJMPAL019076-04B (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL019076-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 5297
- Protocol: St. Jude
- WBC at Diagnosis: 2.8
- Initial Therapy: ALL
- Karyotype: 45,XY,dic(9;16)(p11;p11.2),i(17)(q10)[21]
- WHO ALAL Classification: B/M
- WHO Dx: B-ALL
- WHO RL1: B/M
